Somatic mutation profile of tumor specimen C3N-00386-02 (aliquot CPT0016220009) from CPTAC case C3N-00386, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 44.3 years (16,190 days).
Specimen C3N-00386-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f91338e-e9b6-4009-9c69-1fbe05d4ff66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00386-71 (Blood Derived Normal), aliquot CPT0016770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59db711c-18c9-454a-b875-458233cc579f

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Splice Site 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 82/337 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- PTEN | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 106/582 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64290343, COSV64290444, COSV64294220; called by muse, varscan2
- CCDC168 | c.5680G>A p.V1894I | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV101468891; called by muse, mutect2, varscan2
- CDH1 | c.830del p.P277Qfs*5 | Frame Shift Del (DEL) | VAF 58/277 reads (21%) | catalogued as COSV55727767; called by mutect2, pindel, varscan2
- CYP2B6 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1263464555; called by muse, mutect2, varscan2
- ITPR2 | c.7013G>A p.R2338Q | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs761715910, COSV101189935; called by muse, mutect2, varscan2
- KLF3 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54710209; called by muse, mutect2, varscan2
- KRT14 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs1328900707, COSV51421510; called by muse, mutect2, varscan2
- MAST3 | c.2720C>T p.T907M | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs778781169, COSV99445166; called by muse, mutect2, varscan2
- MCM4 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777231755, COSV100031648; called by muse, mutect2, varscan2
- NAT10 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757857939; called by muse, mutect2, varscan2
- PHOX2A | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV53356195; called by muse, mutect2, varscan2
- PROM2 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs1187293583, COSV58299224; called by muse, mutect2, varscan2
- PTPRQ | c.1205C>A p.A402E (on ENST00000616559; = p.A360E on NM_001145026.2) | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV99883661; called by muse, varscan2
- SCN10A | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs750676187; called by muse, mutect2, varscan2
- SLC6A2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557196282, COSV54921528; called by muse, mutect2, varscan2
- BIRC6 | c.14173C>G p.R4725G | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DRC3 | c.823-1C>T p.X275_splice | Splice Site (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- FOXK1 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- OR5H14 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PTCHD1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTEN | c.417_427del p.L140Qfs*36 | Frame Shift Del (DEL) | VAF 129/398 reads (32%) | called by pindel, varscan2
- RASAL2 | c.2849C>G p.S950C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2
- SPTBN1 | c.4997+1G>A p.X1666_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.2879G>A p.R960H (on ENST00000648592; = p.R926H on NM_182973.2) | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- UBE2A | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- BEX1 | c.288G>T p.L96= | Silent (SNP) | VAF 72/283 reads (25%) | catalogued as COSV101022507; called by muse, mutect2, varscan2
- EIPR1 | c.1116C>G p.L372= | Silent (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- FAM83H | c.1254C>T p.G418= | Silent (SNP) | VAF 12/400 reads (3%) | catalogued as rs782802376, COSV101187073; called by muse, mutect2
- FARP2 | c.1662A>G p.L554= | Silent (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- FLNA | c.5898C>A p.G1966= (on ENST00000369850 / NM_001110556.2; = p.G1958= on NM_001456.3) | Silent (SNP) | VAF 15/336 reads (4%) | called by muse, mutect2
- KDM4A | c.2547C>T p.H849= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as rs755367705; called by muse, mutect2, varscan2
- TRO | c.3877C>T p.L1293= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV51503706; called by muse, mutect2
- ATP11B | c.-71G>T | 5'UTR (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
